FM case AD12759 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/39365afd-3a8d-4aca-9396-1633e4895a06

Male, 62.3 years: diagnosis not reported by GDC; metastasis biopsied or resected from the skin. Sample type: Metastatic.
